Surgical pathology report (de-identified scan), TCGA case TCGA-85-A50M, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A50M-01A (Primary Tumor).

[page 1 of 2]
Gross Description: Tumor is located in right upper lobes, ill - margins with 7x7x7cm in size, soft and necrotic-gray surface.

Paratracheal, subcarinall and interlobar lymph nodes are 1.5cm in maximum size, black in color. Tumor is located in right upper lobes, ill - margins with 7x7x7cm in size, soft and necrotic-gray surface.

Paratracheal, subcarinall and interlobar lymph nodes are 1.5cm in maximum size, black in color.

Microscopic Description: Tumor tissue arranges in the form of group or sheets or trabeculae of tumor cells, invading in beginn brochus tissue. The malignant cells have moderate, eosinophilic cytoplasm. The nuclei are enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are common. Tumor is invasion of lymphocytes.

Diagnosis Details: Squamous cell carcinoma, grade II

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Pneumonectomy

Tumor site: Lung

Tumor size: 7 x 7 x 7 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Other tumor nodules: Not specified

Lymph nodes: 0/3 positive for metastasis (Paratracheal, subcarinal and interlobar lymph node 0/3)

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

ICD-O-3
carcinoma, squamous cell, nos
8070/3
Site: lung, (R) upper lobe C34.1
hw
10/29/12

[page 2 of 2]
Comments: Right- upper

HIP-IA Discrepancy		X
Reviewed: [Signature]	Date Reviewed: 10/29/12	

Source: NCI Genomic Data Commons file fcd7fb20-99d6-44ca-bf41-1bf3c982466f (TCGA-85-A50M.22D952B9-47B2-409A-8177-56A2537BE21D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).